CCDI case PBBYHV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/15c1386a-96da-4dd2-ae08-14f8dbf336c2

Demographics
Sex at birth: male.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 17.5 years (6,394 days).

Biospecimens (3 samples)
- Sample 0DKMFZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKMG4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKMG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
